Gene-level copy-number profile of tumor specimen TCGA-D8-A27V-01A from TCGA case TCGA-D8-A27V, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.9 years (22,958 days).
Specimen TCGA-D8-A27V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.12f03a32-be3d-40c0-b380-b104d972a3f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A27V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e14af981-97c7-4380-b4b5-d864812bec42

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,011; copy number 2: 3,833; copy number 3: 1,440; copy number 4: 34,256; copy number 5: 220; copy number 6: 15,080; copy number 8: 2,676; copy number 10: 283; copy number 11: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A27V-01A-12D-A17C-01): tumor purity 0.64, ploidy 2.28, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 302 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:48,762,235–48,817,214, 1 gene, copy number 10 (within-gene range 2–10): TTLL6.
- chr17:48,831,018–56,511,659, 166 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr17:59,197,566–62,627,590, 105 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr17:67,991,099–68,422,731, 19 genes, copy number 11: C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6.
- chr17:69,414,697–69,553,865, 1 gene, copy number 10 (within-gene range 1–10): MAP2K6.
- chr17:69,477,139–70,180,044, 10 genes, copy number 10: AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2.

Autosomal genes at a single copy (total copy number 1): 2,011. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
